Gene-level copy-number profile of tumor specimen HTMCP-03-06-02128-01A from CGCI case HTMCP-03-06-02128, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G2; Age at diagnosis: 46.7 years (17,050 days).
Specimen HTMCP-03-06-02128-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4cc5653-b412-4127-9720-863581299ae6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02128-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/ae711aa1-fc1a-4b8c-9506-14df6646b96b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 52; copy number 2: 12,940; copy number 3: 6,618; copy number 4: 32,577; copy number 5: 664; copy number 6: 1,960; copy number 7: 2,080; copy number 8: 122; copy number 9: 952; copy number 10: 358; copy number 11: 15; copy number 12: 2; copy number 13: 28.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr4:9,459,255–9,460,244, 1 gene: OR7E86P.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr10:87,504,875–88,049,823, 15 genes: MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,355 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:162,486,541–198,123,232, 631 genes, copy number 9–10 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 9: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 9: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes, copy number 9 (within-gene range 4–9): TRGV5P, TRGV5.
- chr8:101,686,542–145,066,685, 635 genes, copy number 9–12 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 10: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:22,096,032–22,511,024, 66 genes, copy number 9–13 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 13: TRAC.

Autosomal genes at a single copy (total copy number 1): 52. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
